Somatic mutation profile of tumor specimen MBCproject_0080_T1_WES (aliquot MBCproject_0080_T1_WES_1) from CMI case MBCproject_0080, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.1 years (14,647 days).
Specimen MBCproject_0080_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bc6d0cc-ad7c-4967-98e4-58697923612e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0080_SALIVA (Saliva), aliquot MBCproject_0080_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71dbc919-2327-44ef-bbd8-4357276bf4f5

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 2, 5'UTR 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMBX1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs911272430, COSV63601809; called by muse, mutect2, varscan2
- GLI2 | c.3500C>T p.P1167L (on ENST00000361492 / NM_001374353.1; = p.P1184L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs754763067, CM145393; called by muse, mutect2, varscan2
- GRK1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441327018; called by muse, mutect2, varscan2
- LILRB2 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 41/362 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs775537731, COSV58743576; called by muse, mutect2, varscan2
- PCLO | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 33/1122 reads (3%) | catalogued as COSV100435027; called by muse, mutect2
- SP3 | c.1915A>T p.R639* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as COSV59466226; called by muse, mutect2
- SRRM2 | c.7174C>T p.R2392C | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1400971503; called by muse, mutect2, varscan2
- SRRM5 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 110/1030 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1264021356; called by mutect2, varscan2
- TMEM53 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1393674291; called by muse, mutect2
- ABCG4 | c.1713C>G p.V571= | Splice Region (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- ARID1A | c.1670dup p.S558Vfs*65 | Frame Shift Ins (INS) | VAF 47/461 reads (10%) | called by mutect2, pindel, varscan2
- HTT | c.4118C>G p.A1373G | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- NRTN | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 24/525 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CATSPER4 | c.126C>T p.P42= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- NEFM | c.270C>T p.P90= | Silent (SNP) | VAF 88/798 reads (11%) | catalogued as rs1470366115, COSV55331651; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1119G>A p.P373= | Silent (SNP) | VAF 36/365 reads (10%) | catalogued as rs543943795, COSV58743022; called by muse, mutect2, varscan2
- KLHL7 | c.-148C>G | 5'UTR (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2
- RBM10 | c.-71dup | 5'UTR (INS) | VAF 62/505 reads (12%) | called by mutect2, pindel, varscan2
